Gene-level copy-number profile of tumor specimen TCGA-S9-A6U0-01A from TCGA case TCGA-S9-A6U0, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.2 years (16,890 days).
Specimen TCGA-S9-A6U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.ef3467e8-76ae-470c-8f86-710045df9058.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S9-A6U0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a62dae9e-4825-497c-a6f7-aa4fbf8c18df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 5,116; copy number 2: 51,522; copy number 3: 3,011; copy number 4: 25; copy number 5: 2; copy number 8: 3; copy number 10: 2; copy number 15: 22; copy number 17: 5; copy number 25: 1; copy number 27: 1; copy number 47: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S9-A6U0-01A-12D-A32A-01): tumor purity 0.9, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,178,589–22,128,103, 45 genes (within-gene range 0–1): IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:1,526,637–2,618,739, 13 genes: ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1.
- chr10:3,066,333–3,298,137, 10 genes (within-gene range 0–1): PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2.
- chr10:3,532,094–3,556,314, 1 gene: AL357833.1.
- chr10:3,809,835–4,089,013, 6 genes: AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2.
- chr10:4,384,246–4,785,100, 8 genes (within-gene range 0–26): LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,872,982–54,298,245, 22 genes, copy number 15 (within-gene range 2–15): SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA.
- chr7:54,185,071–55,260,256, 19 genes, copy number 47 (within-gene range 3–47): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr8:141,581,658–141,786,313, 2 genes, copy number 5: AC025839.1, MIR1302-7.
- chr10:2,724,819–2,728,267, 1 gene, copy number 25: AL355361.1.
- chr10:3,397,505–3,502,915, 2 genes, copy number 10 (within-gene range 0–10): AL356433.1, LINC02669.
- chr10:3,748,966–3,785,281, 3 genes, copy number 8: AL450322.2, AL450322.1, KLF6.
- chr10:4,201,141–4,243,912, 1 gene, copy number 27 (within-gene range 0–27): LINC00702.
- chr10:4,962,436–5,018,031, 5 genes, copy number 17: U8, AKR1C1, AKR1C2, AL391427.1, U8.

Autosomal genes at a single copy (total copy number 1): 2,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
